Gene-level copy-number profile of tumor specimen TCGA-51-6867-01A from TCGA case TCGA-51-6867, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage I; Age at diagnosis: 72.6 years (26,523 days).
Specimen TCGA-51-6867-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.54d737d2-27bb-4d04-88ab-44037b9b6167.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-51-6867-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate.
https://portal.gdc.cancer.gov/files/b4d0e223-8ca3-42fd-96d1-5e87fd098da1

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 1,454; copy number 2: 21,978; copy number 3: 12,776; copy number 4: 12,783; copy number 5: 8,370; copy number 6: 804; copy number 7: 612; copy number 8: 263; copy number 9: 61; copy number 10: 234; copy number 11: 39; copy number 12: 23; copy number 13: 66; copy number 14: 179; copy number 16: 128; copy number 17: 49.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 10,828 genes in 21 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–248,919,946, 2,604 genes, copy number 5 (broad region; genes not listed).
- chr2:38,814–28,802,940, 495 genes, copy number 5 (broad region; genes not listed).
- chr2:34,799,850–35,185,689, 1 gene, copy number 5 (within-gene range 4–5): AC012593.1.
- chr2:34,998,273–80,648,861, 779 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr2:200,510,008–203,961,577, 123 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr3:96,349,554–107,463,912, 153 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr3:108,125,821–119,677,454, 176 genes, copy number 5–7 (broad region; genes not listed).
- chr3:119,969,044–131,016,712, 284 genes, copy number 7 (broad region; genes not listed).
- chr3:134,597,801–135,260,467, 1 gene, copy number 10 (within-gene range 3–10): EPHB1.
- chr3:134,774,543–142,807,888, 135 genes, copy number 8–10 (within-gene range 4–10) (broad region; genes not listed).
- chr3:145,523,538–145,963,623, 5 genes, copy number 6: LARP7P4, GM2AP1, RPL21P39, AC055758.2, AC055758.1.
- chr3:147,844,123–198,222,513, 907 genes, copy number 5–17 (broad region; genes not listed).
- chr5:58,198–45,895,970, 709 genes, copy number 5–10 (broad region; genes not listed).
- chr6:48,952,070–50,913,256, 33 genes, copy number 7: AL022099.1, AL589994.1, AL589994.2, FO393413.1, RNU7-65P, EEF1A1P42, MMUT, CENPQ, GLYATL3, C6orf141, CYP2AC1P, RHAG, CRISP2, AL121974.1, AL121950.1, CRISP3, PGK2, AL359458.1, CRISP1, DEFB133, DEFB114, DEFB113, DEFB110, DEFB112, AL138826.1, AL132799.1, AL360175.1, AL135908.1, TFAP2D, TFAP2B, RPS17P5, AL049693.1, FTH1P5.
- chr6:65,788,417–87,016,679, 260 genes, copy number 6–7 (within-gene range 1–7) (broad region; genes not listed).
- chr9:14,475–12,300,451, 162 genes, copy number 5 (broad region; genes not listed).
- chr11:13,276,652–47,164,385, 506 genes, copy number 5–11 (within-gene range 2–11) (broad region; genes not listed).
- chr12:132,457,160–133,214,832, 41 genes, copy number 7: AC079031.1, AC079031.2, FBRSL1, AC131212.3, AC131212.2, MIR6763, AC131212.1, LRCOL1, P2RX2, AC131212.4, POLE, PXMP2, AC135586.2, PGAM5, RNA5SP379, ANKLE2, AC135586.1, GOLGA3, CHFR, RPS11P5, RNU6-327P, AC127070.4, AC127070.1, AC127070.3, AC127070.2, ZNF605, NANOGNBP2, ZNF26, RNU4ATAC12P, ZNF84-DT, PTP4A1P2, ZNF84, AC073911.1, AC073911.2, ZNF140, ZNF891, AC026786.2, RPL23AP67, ZNF10, AC026786.1, ZNF268.
- chr15:65,226,472–101,933,350, 959 genes, copy number 5 (broad region; genes not listed).
- chr19:17,351,450–44,725,217, 1,037 genes, copy number 5–8 (within-gene range 3–8) (broad region; genes not listed).
- chr20:87,250–64,313,132, 1,458 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,454. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
